CCDI case PBCJXE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/da4160e7-9f8c-4369-bd45-7b51bb6445f0

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,229 days).

Biospecimens (3 samples)
- Sample 0DVU3B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVU3J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVU3S: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
